Gene-level copy-number profile of tumor specimen TARGET-10-PAPFWH-09A from TARGET case TARGET-10-PAPFWH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.7 years (6,103 days).
Specimen TARGET-10-PAPFWH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.2bfff546-7452-5b62-a57b-8d5aa74b6944.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PAPFWH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate.
https://portal.gdc.cancer.gov/files/f336efad-1a4c-4c79-9049-6a0097f6405f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 797; copy number 1: 206; copy number 2: 59,258; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 276 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,032,172–35,146,435, 4 genes: ZMYM1, RPL12P45, EFCAB14P1, AL590434.1.
- chr1:198,777,861–198,937,471, 3 genes (within-gene range 0–2): MIR181A1HG, MIR181B1, MIR181A1.
- chr4:10,284,961–10,285,708, 1 gene: AC006499.3.
- chr4:94,743,668–95,158,448, 2 genes (within-gene range 0–2): BMPR1B-DT, BMPR1B.
- chr7:38,291,616–38,311,808, 4 genes: TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:50,304,068–50,405,101, 1 gene (within-gene range 0–2): IKZF1.
- chr7:142,320,677–142,793,368, 71 genes (broad region; genes not listed).
- chr9:37,002,697–37,008,040, 1 gene: AL161781.2.
- chr11:56,526,568–56,527,503, 1 gene (within-gene range 0–2): OR5M5P.
- chr12:11,541,395–12,829,981, 32 genes: AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47.
- chr14:22,438,547–22,509,406, 39 genes: TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32.
- chr14:106,389,392–106,762,588, 64 genes (broad region; genes not listed).
- chr15:34,358,633–34,521,791, 10 genes (within-gene range 0–2): LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr19:36,687,612–36,916,291, 10 genes: ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61.
- chr20:47,209,214–47,493,085, 8 genes (within-gene range 0–2): ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P.
- chr22:22,030,934–22,215,270, 20 genes (within-gene range 0–1): IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60.
- chr22:22,219,647–22,245,515, 4 genes: IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:27,044,001–27,045,315, 1 gene, copy number 5: AL008638.4.

Autosomal genes at a single copy (total copy number 1): 202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
